TCGA case TCGA-P3-A6T4 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: Fred Hutchinson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7885e34-d5dc-4256-a4ad-944a27dfcfc2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Dead; Days to death: 62 days.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 54.8 years (20,027 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T4; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 14; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 62 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Tobacco smoking onset year: 1968.
- Alcohol history: Yes; Alcohol drinks per day: 3.5; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-P3-A6T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-P3-A6T4-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-P3-A6T4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-P3-A6T4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Positive; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 62 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 62 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 62 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-P3-A6T4-01A-11D-A34I-01): tumor purity 0.45, ploidy 3.26, whole-genome doublings 1.
